Somatic mutation profile of tumor specimen C3L-01553-01 (aliquot CPT0065930009) from CPTAC case C3L-01553, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 60.0 years (21,899 days).
Specimen C3L-01553-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86f78ccc-0efd-4d63-8e57-8d2ece72676c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01553-31 (Blood Derived Normal), aliquot CPT0067730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41c1fc0b-5367-4380-ad39-352fb51bbd85

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Frame Shift Del 9, Intron 6, Nonsense Mutation 6, Silent 5, Splice Region 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C12orf29 | c.184T>C p.C62R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs763266905; called by muse, varscan2
- CCER1 | c.1104C>A p.F368L | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100726943; called by muse, mutect2, varscan2
- CCNB1IP1 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.338); catalogued as rs778623292; called by muse, varscan2
- CNOT1 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 40/130 reads (31%) | catalogued as COSV100410422; called by mutect2, varscan2
- GRIN2B | c.2782G>T p.E928* | Nonsense Mutation (SNP) | VAF 17/435 reads (4%) | catalogued as rs1555102531, COSV74207623; called by muse, mutect2
- MAP3K19 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100208265; called by muse, mutect2, varscan2
- NUGGC | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 21/412 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV58439356; called by muse, mutect2
- SEMA4C | c.1609C>G p.L537V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as rs1394615012; called by muse, mutect2
- TRPM7 | c.1376T>C p.I459T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs55924090; called by muse, mutect2, varscan2
- TSHZ1 | c.2309C>T p.P770L (on ENST00000580243 / NM_001308210.2; = p.P725L on NM_005786.6) | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59016735; called by muse, mutect2
- USP24 | c.6916C>T p.H2306Y | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs763678402; called by muse, mutect2, varscan2
- ZBTB3 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779542676, COSV101188997; called by muse, mutect2, varscan2
- ANK3 | c.10132C>A p.P3378T | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATXN7L3 | c.880C>T p.Q294* (on ENST00000389384 / NM_001382309.1; = p.Q301* on NM_001382308.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- BCCIP | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, varscan2
- BCL2L13 | c.1412T>C p.I471T | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- C5 | c.3481del p.L1161Wfs*2 | Frame Shift Del (DEL) | VAF 71/302 reads (24%) | called by mutect2, pindel, varscan2
- CALHM4 | c.912A>T p.E304D (on ENST00000368596 / NM_001366078.1; = p.E118D on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, varscan2
- CUBN | c.4978A>G p.I1660V | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- DDR1 | c.1003T>C p.S335P | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- DYNC1H1 | c.13872del p.F4624Lfs*27 | Frame Shift Del (DEL) | VAF 101/502 reads (20%) | called by mutect2, pindel, varscan2
- GGT2 | c.1656_1657del p.G553Lfs*25 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | called by mutect2, varscan2
- GLRB | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KCNK3 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- KDM5C | c.3615T>A p.C1205* | Nonsense Mutation (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- KIAA0825 | c.1551_1552insAG p.E518Rfs*28 | Frame Shift Ins (INS) | VAF 148/441 reads (34%) | called by mutect2, pindel, varscan2
- KLRC4 | c.12_25del p.Q4Hfs*17 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel
- LRSAM1 | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MAOB | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAST1 | c.327G>A p.S109= | Splice Region (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- MMP2 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MON2 | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- NAIP | c.379del p.L127Ffs*2 | Frame Shift Del (DEL) | VAF 43/421 reads (10%) | called by mutect2, pindel, varscan2
- OR52H1 | c.262del p.W88Gfs*2 (on ENST00000322653; = p.W94Gfs*2 on NM_001005289.1) | Frame Shift Del (DEL) | VAF 57/196 reads (29%) | called by mutect2, pindel, varscan2
- PBRM1 | c.813G>A p.K271= | Splice Region (SNP) | VAF 39/76 reads (51%) | called by muse, mutect2, varscan2
- PBX3 | c.1086C>A p.Y362* | Nonsense Mutation (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- RAMAC | c.26dup p.F11Vfs*2 | Frame Shift Ins (INS) | VAF 39/116 reads (34%) | called by mutect2, pindel, varscan2
- RHPN1 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SH3D21 | c.345G>A p.E115= (on ENST00000453908 / NM_001162530.2; = p.E4= on NM_024676.5) | Splice Region (SNP) | VAF 24/119 reads (20%) | called by muse, mutect2, varscan2
- SORCS1 | c.1766del p.L589Cfs*12 | Frame Shift Del (DEL) | VAF 37/178 reads (21%) | called by mutect2, pindel, varscan2
- VHL | c.261_262del p.W88Afs*43 | Frame Shift Del (DEL) | VAF 111/284 reads (39%) | called by mutect2, pindel, varscan2
- VIPAS39 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- VPS13A | c.8379del p.K2793Nfs*6 | Frame Shift Del (DEL) | VAF 53/230 reads (23%) | called by mutect2, pindel, varscan2
- ZC3HAV1 | c.1907C>A p.S636* | Nonsense Mutation (SNP) | VAF 35/156 reads (22%) | called by muse, mutect2, varscan2
- NCKAP5 | c.5293A>C p.R1765= | Silent (SNP) | VAF 38/225 reads (17%) | catalogued as COSV100494932; called by muse, mutect2, varscan2
- PALD1 | c.252G>T p.R84= | Silent (SNP) | VAF 39/164 reads (24%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1887T>C p.A629= | Silent (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- SPTBN1 | c.3549C>A p.A1183= | Silent (SNP) | VAF 19/65 reads (29%) | called by muse, varscan2
- ZNF836 | c.1365A>C p.S455= | Silent (SNP) | VAF 47/205 reads (23%) | called by muse, mutect2, varscan2
- ATG3 | c.794+38A>G | Intron (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- C12orf75 | c.107+15_107+16del | Intron (DEL) | VAF 19/154 reads (12%) | called by mutect2, pindel, varscan2
- COL4A2 | c.648+165T>A | Intron (SNP) | VAF 89/380 reads (23%) | called by muse, mutect2, varscan2
- MDH2 | c.67-18C>T | Intron (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- NACA | c.71-1832G>T | Intron (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- SDF4 | c.557-85A>G | Intron (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2, varscan2
